Somatic mutation profile of tumor specimen TCGA-IA-A40X-01A (aliquot TCGA-IA-A40X-01A-11D-A25F-10) from TCGA case TCGA-IA-A40X, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 49.9 years (18,239 days).
Specimen TCGA-IA-A40X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ceff4326-adf9-455e-a307-9b873cfdd160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IA-A40X-10A (Blood Derived Normal), aliquot TCGA-IA-A40X-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2bd4dd3-cbc3-42ad-9780-468af777e46b

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPIFB3 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs774954137, COSV64958064; called by muse, mutect2, varscan2
- C7orf31 | c.729A>C p.K243N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.984); catalogued as COSV52219709, COSV99384047; called by muse, mutect2
- C9orf153 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV59252191; called by muse, mutect2, varscan2
- CRACR2A | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV52917560; called by muse, mutect2, varscan2
- CRBN | c.533A>C p.Q178P | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51642483; called by muse, mutect2, varscan2
- CTNNA3 | c.2345G>A p.C782Y | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV65528905; called by muse, mutect2, varscan2
- FAM83C | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV65584198; called by muse, mutect2, varscan2
- GAB3 | c.1624T>C p.S542P | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65820587; called by muse, mutect2, varscan2
- IL21R | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV61972273; called by muse, mutect2, varscan2
- IL21R | c.887T>C p.F296S | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV61972279; called by muse, mutect2, varscan2
- KCNJ3 | c.244T>C p.W82R | Missense Mutation (SNP) | VAF 30/461 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54543203; called by muse, mutect2
- KCNN4 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1422149651, COSV53456957; called by muse, mutect2, varscan2
- KLHDC8B | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs753292522, COSV60412501; called by muse, mutect2, varscan2
- MMP11 | c.1354G>T p.G452C | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53157683; called by muse, mutect2, varscan2
- MTMR2 | c.1924G>A p.V642I | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.039); catalogued as COSV57690150; called by muse, mutect2, varscan2
- NUP98 | c.2110A>T p.S704C | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV61437608; called by muse, mutect2, varscan2
- OTX1 | c.344T>A p.V115E | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV56995937; called by muse, mutect2, varscan2
- SLC11A1 | c.222C>A p.D74E | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51919035; called by muse, mutect2, varscan2
- TMPRSS3 | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV52306955; called by muse, mutect2, varscan2
- TNRC18 | c.4867C>T p.Q1623* | Nonsense Mutation (SNP) | VAF 45/107 reads (42%) | catalogued as COSV68164242; called by muse, mutect2, varscan2
- TRIM37 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV51887997; called by muse, mutect2, varscan2
- ZNF536 | c.1542G>C p.E514D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV62832815; called by muse, mutect2, varscan2
- LRRC8B | c.336A>G p.K112= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as COSV58376805; called by muse, mutect2, varscan2
- SLC6A19 | c.1374C>T p.L458= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV58674113; called by muse, mutect2, varscan2
- VCX | c.354C>T p.S118= | Silent (SNP) | VAF 76/236 reads (32%) | catalogued as rs200229312, COSV58231915; called by muse, varscan2
- PLD3 | c.102+13C>G | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10360+1893G>A | Intron (SNP) | VAF 33/112 reads (29%) | catalogued as rs145004106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
